Somatic mutation profile of tumor specimen MP2PRT-PASRHM-TMP1-A (aliquot MP2PRT-PASRHM-TMP1-A-1-0-D-A80I-36) from MP2PRT case MP2PRT-PASRHM, project MP2PRT-ALL (Molecular Profiling to Predict Response to Treatment for Acute Lymphoblastic Leukemia). Sex at birth: male; Vital status: Dead; Primary diagnosis: Acute leukemia, NOS; Tissue or organ of origin: Bone marrow; Age at diagnosis: 3.3 years (1,210 days).
Specimen MP2PRT-PASRHM-TMP1-A: Sample type: Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Whole Bone Marrow; Biospecimen anatomic site: Bone Marrow; Preservation method: Cryopreserved.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 9dbe094d-903f-4546-a3bb-1c6bf146ae9b.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MP2PRT-PASRHM-NB1-A (Blood Derived Cancer - Peripheral Blood, Post-treatment; tissue type Normal — post-treatment blood used as the germline comparator), aliquot MP2PRT-PASRHM-NB1-A-1-0-D-A80I-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/84006392-026e-4c7a-a588-0bc88417c2e9

The open-access MAF lists 11 somatic variants for this specimen: 8 protein-altering or splice-affecting, 3 silent.
By variant classification: Missense Mutation 7, Silent 3, In Frame Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- NRAS | c.38G>A p.G13D | Missense Mutation (SNP) | VAF 44/337 reads (13%) | hotspot (GDC flag); SIFT deleterious (0.05); PolyPhen benign (0.323); catalogued as rs121434596, CM071907, COSV54736416, COSV54736480, COSV54736793; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- CACNA1I | c.6022C>T p.R2008W | Missense Mutation (SNP) | VAF 51/474 reads (11%) | SIFT deleterious (0.03); PolyPhen benign (0.425); catalogued as rs748106748, COSV60806706; called by muse, mutect2, varscan2
- FGFR4 | c.2129G>A p.R710Q | Missense Mutation (SNP) | VAF 50/840 reads (6%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.489); catalogued as rs140492176; called by muse, mutect2
- SP140L | c.236G>A p.R79H | Missense Mutation (SNP) | VAF 85/217 reads (39%) | SIFT deleterious (0.05); PolyPhen benign (0.01); catalogued as rs757776617, COSV54742185; called by muse, mutect2, varscan2
- CCDC122 | c.189_191del p.A64del | In Frame Del (DEL) | VAF 12/110 reads (11%) | called by pindel, varscan2
- MYO5B | c.2084C>T p.P695L | Missense Mutation (SNP) | VAF 67/744 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2
- NOMO2 | c.2140A>C p.I714L | Missense Mutation (SNP) | VAF 145/1067 reads (14%) | SIFT tolerated (0.09); PolyPhen benign (0.322); called by muse, mutect2, varscan2
- PACRG | c.209C>A p.T70K | Missense Mutation (SNP) | VAF 45/538 reads (8%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.995); called by muse, mutect2
- CACNA1F | c.1449C>T p.G483= | Silent (SNP) | VAF 71/493 reads (14%) | catalogued as rs148184710; called by muse, mutect2, varscan2
- HIF1A | c.2355A>G p.Q785= | Silent (SNP) | VAF 35/428 reads (8%) | called by muse, mutect2
- SMPDL3B | c.543G>A p.P181= | Silent (SNP) | VAF 30/279 reads (11%) | catalogued as rs749669066; called by muse, mutect2, varscan2
